Somatic mutation profile of tumor specimen TCGA-C5-A1MF-01A (aliquot TCGA-C5-A1MF-01A-11D-A13W-08) from TCGA case TCGA-C5-A1MF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 49.0 years (17,911 days).
Specimen TCGA-C5-A1MF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac827ec4-6fb0-42df-b6a5-3737af87fcae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1MF-10A (Blood Derived Normal), aliquot TCGA-C5-A1MF-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edad5c3c-e940-4962-b90f-836f69c39124

The open-access MAF lists 100 somatic variants for this specimen: 74 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 23, Nonsense Mutation 9, RNA 3, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.361A>G p.M121V | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59383244; called by muse, mutect2, varscan2
- ANKRD52 | c.2492T>C p.V831A | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.17); catalogued as COSV57282680; called by muse, mutect2, varscan2
- AQP12A | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs375647576; called by muse, mutect2, varscan2
- ASB4 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV57943147; called by muse, mutect2, varscan2
- ATP8B2 | c.817G>A p.E273K (on ENST00000672630; = p.E240K on NM_001005855.2) | Missense Mutation (SNP) | VAF 17/492 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.388); catalogued as COSV100527700; called by muse, mutect2
- BCORL1 | c.3563C>T p.P1188L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs368883442, COSV54390040; called by muse, mutect2, varscan2
- BHLHE22 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58861275; called by muse, mutect2, varscan2
- BRINP3 | c.1787G>A p.W596* | Nonsense Mutation (SNP) | VAF 188/427 reads (44%) | catalogued as COSV100818430; called by muse, varscan2
- BTN2A2 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV61856657; called by muse, mutect2, varscan2
- CCDC18 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100159288; called by muse, mutect2, varscan2
- CCDC18 | c.2991G>T p.M997I (on ENST00000343253 / NM_001306076.1; = p.M998I on NM_206886.4) | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100159290; called by muse, mutect2
- CCDC91 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 27/159 reads (17%) | catalogued as rs774501403, COSV60339358; called by muse, mutect2, varscan2
- CCR9 | c.456G>A p.M152I (on ENST00000357632 / NM_031200.3; = p.M140I on NM_006641.4) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs568929897, COSV62939854; called by muse, mutect2, varscan2
- CDK13 | c.2917G>A p.D973N | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV51696589; called by muse, mutect2, varscan2
- COL12A1 | c.2561G>T p.G854V | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV59390041; called by muse, mutect2, varscan2
- COL4A5 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.812); catalogued as COSV100086752; called by muse, mutect2
- DGCR2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 150/384 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV54216580; called by muse, mutect2, varscan2
- DIDO1 | c.2071G>C p.D691H | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56614427; called by muse, mutect2, varscan2
- DMD | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.134); catalogued as COSV63736292; called by muse, mutect2, varscan2
- DNAJC14 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV57912233; called by muse, mutect2, varscan2
- DYNC2H1 | c.6323C>G p.S2108C | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62087026; called by muse, mutect2, varscan2
- ECT2L | c.1928C>A p.A643D | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as COSV62882849; called by muse, mutect2, varscan2
- ERCC6L | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV57819470; called by muse, mutect2, varscan2
- FAT2 | c.4846C>G p.Q1616E | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as rs371218309; called by muse, mutect2, varscan2
- FLNA | c.5488G>A p.V1830M (on ENST00000369850 / NM_001110556.2; = p.V1822M on NM_001456.3) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs782505945, COSV61037963; called by muse, mutect2, varscan2
- GPR137 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs754996541, COSV57401083; called by muse, mutect2, varscan2
- GRIK1 | c.2710G>A p.A904T (on ENST00000327783 / NM_001330994.2; = p.A860T on NM_175611.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); catalogued as rs151335244, COSV59859873; called by muse, mutect2, varscan2
- HDAC7 | c.1112C>T p.P371L (on ENST00000427332; = p.P410L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/176 reads (62%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs531168904, COSV50321078; called by muse, mutect2, varscan2
- IL10RB | c.261G>C p.L87F | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99269813; called by muse, mutect2
- LAMB3 | c.3235G>C p.E1079Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV50520303; called by muse, mutect2, varscan2
- LIN9 | c.1360G>T p.E454* (on ENST00000366808 / NM_001270410.2; = p.E399* on NM_173083.3 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/217 reads (12%) | catalogued as COSV60243953; called by muse, mutect2, varscan2
- LRP11 | c.926C>T p.T309I | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV53333080; called by muse, mutect2, varscan2
- LRP6 | c.2797A>C p.T933P | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as COSV53783703; called by muse, mutect2, varscan2
- LRRC41 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs1426786533, COSV58438997; called by muse, mutect2, varscan2
- MDGA2 | c.2966C>T p.A989V (on ENST00000399232 / NM_001113498.2; = p.A691V on NM_182830.4) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs748948616, COSV62079969; called by muse, mutect2, varscan2
- MED13L | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563883392, COSV56116130; called by muse, mutect2, varscan2
- MUC16 | c.25780C>G p.L8594V | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.634); catalogued as COSV67447006, COSV67469286; called by muse, mutect2, varscan2
- MYH10 | c.3564G>C p.K1188N | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as COSV99344308; called by muse, mutect2
- MYH8 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV101238286; called by muse, mutect2
- NBPF3 | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 31/200 reads (16%) | catalogued as COSV59056893, COSV59062649; called by muse, mutect2, varscan2
- OPLAH | c.3479G>A p.R1160H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.836); catalogued as rs1554757807, COSV70677133; called by muse, mutect2, varscan2
- OR10C1 | c.364G>A p.D122N (on ENST00000622521; = p.D120N on NM_013941.3) | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV65823629; called by muse, mutect2
- PCNX2 | c.2332C>T p.R778C | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1422687144, COSV50783100; called by muse, mutect2, varscan2
- PDCD11 | c.3872A>G p.N1291S | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs1293193153, COSV100874252; called by muse, mutect2
- PEX5L | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 253/362 reads (70%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.039); catalogued as COSV55839748, COSV55841791; called by muse, mutect2, varscan2
- PLCG2 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs781016626, COSV63867611; called by muse, mutect2, varscan2
- PRKN | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs529808032, COSV58203788, COSV58274029; called by muse, mutect2, varscan2
- RHOV | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55027291; called by muse, mutect2, varscan2
- RYR2 | c.6133G>C p.E2045Q | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV63664217; called by muse, mutect2, varscan2
- SCN5A | c.5690G>A p.R1897Q (on ENST00000333535 / NM_198056.3; = p.R1896Q on NM_000335.5) | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs761369505, COSV61116660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC61A2 | c.1127C>G p.S376C | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53650719; called by muse, mutect2, varscan2
- SFMBT2 | c.17C>G p.S6* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV62805685; called by muse, mutect2
- SLC17A4 | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as COSV100930521; called by muse, mutect2
- SLC18B1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51593395, COSV99259110; called by muse, mutect2, varscan2
- SMARCC1 | c.1986G>C p.L662F | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54377453; called by muse, mutect2, varscan2
- SYNE2 | c.5758C>T p.Q1920* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV59940508, COSV59950723; called by muse, mutect2, varscan2
- TENM1 | c.901T>A p.S301T | Missense Mutation (SNP) | VAF 69/374 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.152); catalogued as COSV64425643; called by muse, mutect2, varscan2
- THOC2 | c.4736G>A p.G1579E | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.538); catalogued as COSV55540798; called by muse, mutect2, varscan2
- TP63 | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 42/200 reads (21%) | catalogued as COSV53196890, COSV53197182; called by muse, mutect2, varscan2
- TRAV1-2 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1063358; called by muse, mutect2, varscan2
- TRPC1 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.068); catalogued as COSV56423065; called by muse, mutect2
- TTN | c.89194C>A p.L29732I (on ENST00000591111; = p.L22308I on NM_003319.4) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | PolyPhen benign (0.043); catalogued as COSV59901678; called by muse, mutect2, varscan2
- TYK2 | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs777406666, COSV53384957; called by muse, mutect2
- UFC1 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV57086880; called by muse, mutect2, varscan2
- VPS13C | c.1469C>A p.S490* (on ENST00000644861 / NM_020821.3; = p.S447* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 79/221 reads (36%) | catalogued as COSV51123693; called by muse, mutect2, varscan2
- VWF | c.7966_7968del p.G2656del | In Frame Del (DEL) | VAF 89/144 reads (62%) | catalogued as rs768488894; called by pindel, varscan2
- ZBED8 | c.1390A>G p.I464V | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68824360; called by muse, mutect2, varscan2
- ZNF440 | c.1301G>C p.R434T | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.021); catalogued as COSV100407412, COSV100407716; called by muse, mutect2
- ZNF440 | c.1619G>C p.R540T | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100407414; called by muse, mutect2
- ZNF491 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 120/154 reads (78%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771073180, COSV60056731; called by muse, mutect2, varscan2
- ZNF594 | c.440G>C p.R147T | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as rs1356706763, COSV101280378, COSV68385280; called by muse, mutect2
- ZSCAN5A | c.752G>C p.R251T | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.203); catalogued as rs1371614696, COSV54224146; called by muse, mutect2, varscan2
- ZSCAN5B | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV62838418; called by muse, mutect2, varscan2
- DENND4B | c.1513_1517del p.K505Afs*34 | Frame Shift Del (DEL) | VAF 21/52 reads (40%) | called by mutect2, pindel, varscan2
- AKAP13 | c.5247C>T p.F1749= (on ENST00000394518 / NM_007200.5; = p.F1753= on NM_006738.6) | Silent (SNP) | VAF 60/151 reads (40%) | catalogued as COSV63447424; called by muse, mutect2, varscan2
- CDC42BPB | c.4614C>T p.D1538= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs753065038, COSV63473953; called by muse, mutect2, varscan2
- CENPI | c.1443C>G p.L481= | Silent (SNP) | VAF 15/274 reads (5%) | catalogued as COSV99515083; called by muse, mutect2
- GALNT2 | c.1254G>A p.R418= | Silent (SNP) | VAF 52/245 reads (21%) | catalogued as COSV64193015; called by muse, mutect2, varscan2
- HOOK1 | c.906G>A p.L302= | Silent (SNP) | VAF 15/204 reads (7%) | catalogued as COSV100968996; called by muse, mutect2
- HSF5 | c.1167G>A p.E389= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as COSV60415384; called by muse, mutect2, varscan2
- LAMB3 | c.2961G>A p.L987= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV50520305; called by muse, varscan2
- LHFPL4 | c.66C>T p.I22= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV55000944; called by muse, mutect2, varscan2
- LIPH | c.285G>A p.L95= | Silent (SNP) | VAF 47/360 reads (13%) | catalogued as COSV56182902; called by muse, mutect2, varscan2
- MFSD11 | c.981C>T p.L327= | Silent (SNP) | VAF 55/180 reads (31%) | catalogued as rs567481103, COSV100333532; called by muse, mutect2, varscan2
- NAGA | c.624C>A p.I208= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV101124136, COSV67170045; called by muse, mutect2
- NBAS | c.6900G>A p.L2300= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99867720; called by muse, mutect2, varscan2
- PRR5L | c.1011C>T p.S337= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV61120255; called by muse, mutect2, varscan2
- RASA3 | c.2055C>G p.V685= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV61864001; called by muse, mutect2, varscan2
- RIPOR1 | c.657C>T p.F219= (on ENST00000379312 / NM_001193522.2; = p.F215= on NM_024519.4) | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs747087160, COSV50219932; called by muse, mutect2, varscan2
- RNASE6 | c.297C>A p.V99= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as COSV58977290; called by muse, mutect2, varscan2
- RPIA | c.81C>T p.S27= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs771233693, COSV52168223; called by muse, mutect2
- SBDS | c.72G>A p.G24= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs777899269, COSV55887071; called by muse, mutect2, varscan2
- TTN | c.53430T>C p.R17810= (on ENST00000591111; = p.R10386= on NM_003319.4) | Silent (SNP) | VAF 65/182 reads (36%) | catalogued as COSV59901704; called by muse, mutect2, varscan2
- UBXN7 | c.1113C>T p.V371= | Silent (SNP) | VAF 22/380 reads (6%) | catalogued as COSV99580886; called by muse, mutect2
- UCMA | c.144C>T p.F48= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV66321281; called by muse, mutect2, varscan2
- USPL1 | c.780G>A p.S260= | Silent (SNP) | VAF 48/142 reads (34%) | catalogued as rs778232932, COSV54998756, COSV54999434; called by muse, mutect2, varscan2
- ZIC1 | c.360C>G p.L120= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV51550766; called by muse, mutect2, varscan2
- AC024940.1 | n.3339G>C | RNA (SNP) | VAF 29/195 reads (15%) | catalogued as rs1201147793; called by muse, mutect2, varscan2
- DCHS2 | n.5759G>C | RNA (SNP) | VAF 22/64 reads (34%) | catalogued as COSV61768379; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.609T>A | RNA (SNP) | VAF 99/390 reads (25%) | called by muse, mutect2, varscan2
